Gene-level copy-number profile of tumor specimen TCGA-X9-A973-01A from TCGA case TCGA-X9-A973, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 55.2 years (20,146 days).
Specimen TCGA-X9-A973-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.8bad38ee-5f75-4c5f-97dd-b49a46fb3f98.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X9-A973-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/72740982-cb8e-4611-b948-e610cafc17c2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,502; copy number 2: 48,362; copy number 3: 1,395; copy number 4: 7,885; copy number 5: 660; copy number 6: 7; copy number 7: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X9-A973-01A-11D-A386-01): tumor purity 0.68, ploidy 2.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr9:21,966,929–21,995,301, 2 genes: CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 663 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–36,841,373, 651 genes, copy number 5 (broad region; genes not listed).
- chr7:36,919,357–37,117,185, 3 genes, copy number 5: MIR1200, ELMO1-AS1, RPS17P13.
- chr12:130,337,887–130,716,281, 7 genes, copy number 6 (within-gene range 2–6): PIWIL1, AC127071.2, AC127071.3, RIMBP2, AC063926.1, AC063926.3, AC063926.2.
- chr13:90,781,766–90,926,597, 2 genes, copy number 7: RNU6-75P, LINC00410.

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
